Surgical pathology report (de-identified scan), TCGA case TCGA-61-1899, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1899-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LEFT ADNEXUM, LEFT SALPINGO-OOPHORECTOMY -

- A. HIGH GRADE ADENOCARCINOMA (27 CM).
- B. SEROSAL SURFACE FREE.
- C. FOCAL SURFACE ADHESIONS.
- D. FALLOPIAN TUBE, FREE OF TUMOR.

PART 2: POSTERIOR CUL-DE-SAC NODULE, EXCISION -
INVASIVE HIGH GRADE ADENOCARCINOMA.

PART 3: UTERUS, CERVIX, RIGHT ADNEXUM (130 GRAMS), HYSTERECTOMY AND RIGHT SALPINGO-OOPHORECTOMY--

- A. ADENOCARCINOMA INVOLVES UTERINE SEROSA AND FOCALLY OVARIAN SURFACE.
- B. FALLOPIAN TUBE WITH TUBAL INTRAEPITHELIAL CARCINOMA (see comment)
- C. ATROPHIC ENDOMETRIUM.
- D. CERVIX WITH CHRONIC INFLAMMATION AND SQUAMOUS METAPLASIA.

PART 4: LYMPH NODES, RIGHT PELVIC, BIOPSY -

- A. METASTATIC ADENOCARCINOMA INVOLVES ONE OF SEVEN LYMPH NODES (1/7).
- B. EXTRACAPSULAR EXTENSION IS NOT IDENTIFIED.

PART 5: ANTERIOR CUL-DE-SAC, BIOPSY -
NEGATIVE FOR TUMOR.

PART 6: RIGHT PELVIC SIDEWALL, BIOPSY -
NEGATIVE FOR TUMOR.

PART 7: LEFT PELVIC SIDEWALL, BIOPSY -
INVASIVE HIGH GRADE ADENOCARCINOMA.

PART 8: CUL-DE-SAC, BIOPSY -
INVASIVE HIGH GRADE ADENOCARCINOMA.

PART 9: LYMPH NODE, LEFT PELVIC, BIOPSY -

- A. METASTATIC ADENOCARCINOMA INVOLVES TWO OF FIVE LYMPH NODES (2/5).
- B. EXTRACAPSULAR EXTENSION IS NOT IDENTIFIED.

PART 10: LYMPH NODE, RIGHT PERIAORTIC, BIOPSY -
ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 11: LYMPH NODE, LEFT PERIAORTIC, BIOPSY -

- A. METASTATIC ADENOCARCINOMA INVOLVES ONE OF THREE LYMPH NODES (1/3).
- B. EXTRACAPSULAR EXTENSION IS NOT IDENTIFIED.

PART 12: APPENDIX, APPENDECTOMY -
NEGATIVE FOR TUMOR.

PART 13: RIGHT GUTTER, BIOPSY -
NEGATIVE FOR TUMOR.

PART 14: LEFT GUTTER, BIOPSY -
NEGATIVE FOR TUMOR.

PART 15: OMENTUM, OMENTECTOMY -
HIGH GRADE ADENOCARCINOMA.

PART 16: RIGHT DIAPHRAGM, BIOPSY -
NEGATIVE FOR TUMOR.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Left
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 27.0 cm
TUMOR TYPE:	Mixed epithelial tumor
VASCULAR INVASION:	No
TUMOR CAPSULE:	Ruptured
SURFACE IMPLANTS:	Not present
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 16
LYMPH NODES POSITIVE:	Number of positive lymph nodes, Right: 1 Number of positive lymph nodes, Left: 3
LYMPH NODE GROUPS INVOLVED:	Pelvic, Right, Pelvic, Left, Para-aortic, Left
EXTRANODAL EXTENSION:	Yes
T STAGE, PATHOLOGIC:	pT3a
N STAGE, PATHOLOGIC:	pN1
M STAGE, PATHOLOGIC:	pMX

Source: NCI Genomic Data Commons file 1f4742d4-807a-45a0-8c8d-a51c653a92cb (TCGA-61-1899.0B416E24-55C4-4235-B56B-9DC1507EE5EF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).